Somatic mutation profile of tumor specimen 0DC7SS from CCDI case PBBLXS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.9 years (2,157 days).
Specimen 0DC7SS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0508faf4-d4f0-45f1-b872-db1b899d39de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC7T3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cd12c3c-b288-454c-a558-53706eeebe07

The open-access MAF lists 59 somatic variants for this specimen: 46 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 7, Nonsense Mutation 5, 3'UTR 3, Splice Site 3, Splice Region 2, Intron 1, Frame Shift Ins 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 173/508 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, varscan2
- ARMC12 | c.770G>A p.R257Q (on ENST00000373866 / NM_001286574.2; = p.R284Q on NM_145028.5) | Missense Mutation (SNP) | VAF 52/686 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs777525803, COSV55361079; called by muse, mutect2
- COL4A4 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV61635475; called by muse, mutect2, varscan2
- DDX58 | c.1806G>C p.R602S | Missense Mutation (SNP) | VAF 175/362 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV65885147; called by muse, mutect2, varscan2
- MMP8 | c.497-1G>T p.X166_splice | Splice Site (SNP) | VAF 450/1000 reads (45%) | catalogued as COSV52633447; called by muse, mutect2, varscan2
- NGF | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 205/840 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754287903, COSV65687683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OXER1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 41/474 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs370198807, COSV99685263; called by muse, mutect2
- PCDHA1 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 582/984 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV100974417; called by mutect2, varscan2
- PHF2 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 299/600 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1434809621, COSV63682054; called by muse, mutect2, varscan2
- PHKA1 | c.2215C>T p.R739* | Nonsense Mutation (SNP) | VAF 207/211 reads (98%) | catalogued as rs1197978742; called by muse, mutect2, varscan2
- PLAT | c.1086-7C>A | Splice Region (SNP) | VAF 285/1597 reads (18%) | catalogued as rs1290527362; called by muse, mutect2, varscan2
- TACC3 | c.2062+7G>T | Splice Region (SNP) | VAF 200/418 reads (48%) | catalogued as rs781143586; called by muse, mutect2
- TPCN2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 122/563 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs375141159; called by muse, mutect2, varscan2
- TULP2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 56/1356 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1352515660, COSV99618082; called by muse, mutect2
- WASF3 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 251/969 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs998700219, COSV58971992; called by muse, varscan2
- XKR7 | c.1689C>A p.Y563* | Nonsense Mutation (SNP) | VAF 245/751 reads (33%) | catalogued as COSV73813513; called by muse, mutect2, varscan2
- ZNF621 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 192/394 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs1203511138; called by muse, mutect2, varscan2
- ZP1 | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 230/820 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99612636; called by muse, mutect2, varscan2
- ABRA | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 552/1420 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADGRG5 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 294/632 reads (47%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ARHGAP6 | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 284/293 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- BCAM | c.723C>A p.Y241* | Nonsense Mutation (SNP) | VAF 303/1177 reads (26%) | called by muse, mutect2, varscan2
- COL22A1 | c.2929C>A p.L977I | Missense Mutation (SNP) | VAF 137/798 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CTTNBP2NL | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 59/820 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.315); called by muse, mutect2
- DAB2 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 144/390 reads (37%) | called by muse, mutect2, varscan2
- DCHS1 | c.1776G>T p.Q592H | Missense Mutation (SNP) | VAF 107/595 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH11 | c.8168C>A p.A2723D | Missense Mutation (SNP) | VAF 22/645 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- ECM1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 501/520 reads (96%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EYA3 | c.731T>A p.V244D | Missense Mutation (SNP) | VAF 583/611 reads (95%) | SIFT tolerated (0.64); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FBXO34 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 479/850 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGF23 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 28/574 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- FNDC1 | c.5675G>T p.G1892V | Missense Mutation (SNP) | VAF 223/465 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR26 | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.317); called by muse, mutect2
- IL1RL2 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 281/596 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLC2 | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 131/560 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRBOX1 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 309/693 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LACC1 | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 286/1199 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LGALS9B | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 63/484 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- LPIN2 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 225/539 reads (42%) | called by muse, mutect2, varscan2
- MGA | c.7300_7303dup p.R2435Pfs*5 (on ENST00000219905 / NM_001164273.1; = p.R2226Pfs*5 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 180/429 reads (42%) | called by pindel, varscan2
- OFD1 | c.1221+2T>C p.X407_splice | Splice Site (SNP) | VAF 221/240 reads (92%) | called by muse, mutect2, varscan2
- OTULINL | c.679A>G p.N227D | Missense Mutation (SNP) | VAF 487/870 reads (56%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PKP3 | c.2078-1G>T p.X693_splice | Splice Site (SNP) | VAF 440/943 reads (47%) | called by muse, mutect2, varscan2
- SYNE1 | c.6130C>A p.Q2044K (on ENST00000367255 / NM_182961.4; = p.Q2051K on NM_033071.3) | Missense Mutation (SNP) | VAF 46/812 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2
- TAOK3 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); called by muse, mutect2
- TNRC6B | c.1058C>A p.A353E | Missense Mutation (SNP) | VAF 155/448 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- CXCR1 | c.975G>T p.L325= | Silent (SNP) | VAF 192/478 reads (40%) | catalogued as rs1247189298; called by muse, mutect2, varscan2
- GNAS | c.195C>A p.G65= | Silent (SNP) | VAF 107/335 reads (32%) | catalogued as rs750264533, COSV58328930; called by muse, mutect2, varscan2
- GSG1L2 | c.417C>T p.S139= | Silent (SNP) | VAF 214/570 reads (38%) | catalogued as rs1313609953, COSV101243926; called by muse, mutect2
- MUC16 | c.16140G>A p.L5380= | Silent (SNP) | VAF 86/593 reads (15%) | called by muse, mutect2, varscan2
- TMEM26 | c.153G>A p.A51= | Silent (SNP) | VAF 182/557 reads (33%) | catalogued as rs761541357, COSV67492899; called by muse, mutect2, varscan2
- TTL | c.972G>A p.E324= | Silent (SNP) | VAF 362/775 reads (47%) | called by muse, mutect2, varscan2
- ZNF213 | c.492G>A p.P164= | Silent (SNP) | VAF 167/514 reads (32%) | catalogued as rs745880799, COSV67727983; called by muse, mutect2, varscan2
- CRNDE | n.189C>T | RNA (SNP) | VAF 174/436 reads (40%) | called by muse, mutect2, varscan2
- DIS3 | c.*4538_*4539dup | 3'UTR (INS) | VAF 173/971 reads (18%) | called by mutect2, pindel, varscan2
- OST4 | c.*17G>T | 3'UTR (SNP) | VAF 143/264 reads (54%) | called by muse, mutect2, varscan2
- PSTPIP2 | c.-35G>C | 5'UTR (SNP) | VAF 214/409 reads (52%) | called by muse, mutect2, varscan2
- SLC43A1 | c.693-41G>A | Intron (SNP) | VAF 84/393 reads (21%) | catalogued as rs761057792; called by muse, mutect2, varscan2
- WNT7B | c.*42G>A | 3'UTR (SNP) | VAF 64/135 reads (47%) | catalogued as rs369203607; called by muse, mutect2, varscan2
